Somatic mutation profile of tumor specimen 0DHY4G from CCDI case PBBUVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,778 days).
Specimen 0DHY4G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dce6c285-9c74-4418-9777-aee7fde2b989.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY30 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c4b136b-0eda-46fe-8266-53f8a8c3b38b

The open-access MAF lists 63 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Intron 10, Splice Site 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS1 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs767493061, COSV60219729; called by mutect2, varscan2
- CDH13 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV104391617, COSV51817875; called by muse, mutect2, varscan2
- DSCAM | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as rs752670424, COSV68022860; called by muse, mutect2, varscan2
- KCNN3 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1437869897; called by muse, mutect2
- MYO3A | c.3574dup p.M1192Nfs*3 | Frame Shift Ins (INS) | VAF 114/373 reads (31%) | catalogued as rs757810767; called by mutect2, varscan2
- PDE1B | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs779973236; called by muse, mutect2, varscan2
- PDE6B | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0.104); catalogued as rs146599285; called by muse, mutect2, varscan2
- PROSER1 | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.518); catalogued as rs765915347, COSV61487509; called by muse, mutect2, varscan2
- PUDP | c.29A>T p.H10L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV101127962; called by muse, mutect2, varscan2
- SETX | c.5735T>C p.M1912T | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as rs202124856; called by muse, mutect2, varscan2
- SLC44A3 | c.1237A>T p.R413* (on ENST00000271227 / NM_001114106.3; = p.R365* on NM_152369.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 90/288 reads (31%) | catalogued as rs779526111; called by muse, mutect2, varscan2
- SLC6A4 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.683); catalogued as rs746585288, COSV99911543; called by muse, mutect2, varscan2
- TNC | c.4898C>A p.P1633Q | Missense Mutation (SNP) | VAF 59/472 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs764626466; called by muse, mutect2, varscan2
- TTN | c.29026C>T p.R9676W (on ENST00000591111; = p.R8749W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/200 reads (32%) | PolyPhen possibly damaging (0.9); catalogued as rs375415014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY5 | c.377del p.G126Afs*112 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, varscan2
- ANK3 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- APBB1 | c.1472T>G p.I491S | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC5 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDCA2 | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 195/474 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CDKL3 | c.1137A>T p.E379D | Missense Mutation (SNP) | VAF 98/405 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CFAP44 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP46 | c.1615G>T p.G539W | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNEP1R1 | c.98-1G>T p.X33_splice (on ENST00000427478 / NM_001281789.1; = p.X50_splice on NM_153261.5) | Splice Site (SNP) | VAF 126/201 reads (63%) | called by muse, mutect2, varscan2
- COL24A1 | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 127/482 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPPED1 | c.783G>T p.M261I | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DZANK1 | c.2239C>T p.L747F (on ENST00000262547 / NM_001099407.1; = p.L554F on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FAM47A | c.185G>C p.C62S | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HIRIP3 | c.1201T>G p.S401A | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- NOLC1 | c.1660G>C p.A554P | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPPC | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- OR11H4 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PIK3CG | c.2893T>G p.F965V | Missense Mutation (SNP) | VAF 49/615 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.576+2T>C p.X192_splice | Splice Site (SNP) | VAF 65/70 reads (93%) | called by muse, mutect2, varscan2
- SLC23A2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SLC39A13 | c.1070G>T p.C357F (on ENST00000362021 / NM_001128225.3; = p.C350F on NM_152264.4) | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- THOC7 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, varscan2
- WDR87 | c.7049T>G p.F2350C | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- AK5 | c.463C>A p.R155= (on ENST00000354567 / NM_174858.3; = p.R129= on NM_012093.4) | Silent (SNP) | VAF 149/376 reads (40%) | catalogued as rs769178688; called by muse, mutect2, varscan2
- ARHGEF28 | c.294G>A p.R98= | Silent (SNP) | VAF 52/263 reads (20%) | called by muse, mutect2, varscan2
- CLASP1 | c.1962C>T p.A654= | Silent (SNP) | VAF 53/374 reads (14%) | catalogued as rs565150677; called by muse, mutect2, varscan2
- DDX21 | c.33G>A p.L11= | Silent (SNP) | VAF 12/334 reads (4%) | called by muse, mutect2
- GP6 | c.597G>A p.E199= | Silent (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- HMMR | c.1983G>A p.Q661= | Silent (SNP) | VAF 105/393 reads (27%) | catalogued as rs1435771751; called by muse, mutect2, varscan2
- KBTBD13 | c.504C>A p.G168= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- KDM1A | c.2391C>T p.F797= | Silent (SNP) | VAF 45/337 reads (13%) | called by mutect2, varscan2
- OSCAR | c.426G>C p.P142= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1226016696; called by muse, mutect2, varscan2
- PHLDB3 | c.513C>T p.R171= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs778701550; called by muse, mutect2, varscan2
- RUFY3 | c.1065A>G p.L355= | Silent (SNP) | VAF 98/368 reads (27%) | catalogued as COSV56915236; called by muse, mutect2, varscan2
- TGM6 | c.1671G>A p.P557= | Silent (SNP) | VAF 61/178 reads (34%) | catalogued as rs760476169; called by muse, mutect2, varscan2
- ULBP1 | c.345C>T p.P115= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- ACADVL | c.1077+92A>T | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- CSAG1 | c.168-100C>A | Intron (SNP) | VAF 30/32 reads (94%) | called by muse, mutect2, varscan2
- CYP4F8 | c.-1-75del | Intron (DEL) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- GALNT16 | c.177+66G>T | Intron (SNP) | VAF 31/70 reads (44%) | catalogued as rs893324313; called by muse, mutect2
- GREB1L | c.4735+75C>A | Intron (SNP) | VAF 7/46 reads (15%) | called by mutect2, varscan2
- ITGA5 | c.1463+33C>T | Intron (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- LYPD5 | c.194-65G>T | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- MYADM | chr19:53874147 C>T | 3'Flank (SNP) | VAF 4/28 reads (14%) | catalogued as rs780132482, COSV61239855; called by mutect2, varscan2
- OR2T2 | chr1:248441246 G>A | 5'Flank (SNP) | VAF 12/90 reads (13%) | catalogued as rs763279047; called by muse, mutect2
- PRUNE2 | c.8558-97G>A | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs560263113; called by mutect2, varscan2
- PUSL1 | c.700-59T>C | Intron (SNP) | VAF 52/181 reads (29%) | called by muse, mutect2, varscan2
- RIC8B | c.1451+10591C>G | Intron (SNP) | VAF 15/168 reads (9%) | catalogued as rs985452887; called by muse, mutect2
- SALL3 | c.*62C>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | catalogued as rs540007417; called by muse, mutect2, varscan2
